Somatic mutation profile of tumor specimen TCGA-HW-8320-01A (aliquot TCGA-HW-8320-01A-11D-2395-08) from TCGA case TCGA-HW-8320, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 37.0 years (13,503 days).
Specimen TCGA-HW-8320-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 049f67ac-f0d8-478d-bc36-0c4cc0a083b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HW-8320-10A (Blood Derived Normal), aliquot TCGA-HW-8320-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0febd467-8c14-491f-954d-7fe45e198d2e

The open-access MAF lists 32 somatic variants for this specimen: 21 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 15, Silent 11, Nonsense Mutation 2, Frame Shift Del 2, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 31/76 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- BIRC6 | c.13469C>T p.A4490V | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV70200877; called by muse, mutect2
- CARD14 | c.1379G>A p.S460N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV60125886; called by muse, mutect2, varscan2
- CELSR3 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs1363222850, COSV50986627, COSV99372985; called by muse, mutect2
- CLCA1 | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs747751017, COSV52330168; called by muse, mutect2, varscan2
- CNTD1 | c.257A>T p.K86I | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV59312629; called by muse, mutect2
- CPSF2 | c.1961A>G p.K654R | Missense Mutation (SNP) | VAF 4/97 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.028); catalogued as COSV54100182; called by muse, mutect2
- CTNNBL1 | c.1110C>A p.C370* | Nonsense Mutation (SNP) | VAF 5/92 reads (5%) | catalogued as COSV63746638; called by muse, mutect2
- DOCK11 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.557); catalogued as rs1174860954, COSV52232844; called by muse, mutect2, varscan2
- ENPEP | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.987); catalogued as rs774773801, COSV54455782; called by muse, mutect2, varscan2
- EPPK1 | c.6646G>A p.V2216I | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as rs1307338641, COSV73261585; called by muse, mutect2, varscan2
- ITGAE | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs374525538; called by muse, mutect2
- MGARP | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs765157010, COSV67449777; called by muse, mutect2, varscan2
- MRPL43 | c.586A>G p.M196V | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs576770183, COSV52970983; called by muse, mutect2, varscan2
- NPY2R | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61527310, COSV61529265; called by muse, mutect2, varscan2
- RPS24 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as CM096404, COSV62602947; called by muse, mutect2
- TBC1D19 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | catalogued as COSV53520300; called by muse, mutect2, varscan2
- TP53 | c.699_705del p.Y234Tfs*11 | Frame Shift Del (DEL) | VAF 57/70 reads (81%) | catalogued as COSV53156905; called by mutect2, pindel, varscan2
- ZFPL1 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1434580116, COSV51870882; called by muse, mutect2, varscan2
- ATRX | c.3904dup p.R1302Kfs*7 | Frame Shift Ins (INS) | VAF 40/48 reads (83%) | called by mutect2, varscan2
- ZFHX4 | c.285del p.Y95* | Frame Shift Del (DEL) | VAF 76/250 reads (30%) | called by mutect2, pindel, varscan2
- ADAM28 | c.1416C>T p.C472= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs771905381, COSV56098882; called by muse, mutect2, varscan2
- ALPG | c.1371G>A p.A457= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs374332709; called by muse, mutect2, varscan2
- ANGPT1 | c.990T>C p.R330= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV52451915; called by muse, mutect2, varscan2
- CNTD1 | c.255A>T p.V85= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV59312625; called by muse, mutect2
- HMCN1 | c.9126C>T p.G3042= | Silent (SNP) | VAF 41/83 reads (49%) | catalogued as rs778099815, COSV54928978; called by muse, mutect2, varscan2
- PACSIN3 | c.261G>A p.A87= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as rs960798354, COSV54067455; called by muse, mutect2
- PALM2AKAP2 | c.126C>T p.H42= (on ENST00000259318 / NM_001136562.3; = p.H273= on NM_007203.5) | Silent (SNP) | VAF 94/201 reads (47%) | catalogued as rs750257722, COSV52178214; called by muse, mutect2, varscan2
- RNF112 | c.372T>A p.P124= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV71978969; called by muse, mutect2
- SPAG8 | c.618C>T p.D206= | Silent (SNP) | VAF 33/173 reads (19%) | catalogued as rs386352365, COSV52415358; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.7860C>T p.L2620= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV56415927; called by muse, mutect2, varscan2
- ZNF33B | c.1629T>C p.H543= | Silent (SNP) | VAF 26/142 reads (18%) | catalogued as COSV63943093; called by muse, mutect2, varscan2
